Gene-level copy-number profile of tumor specimen TCGA-85-A512-01A from TCGA case TCGA-85-A512, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 46.0 years (16,811 days).
Specimen TCGA-85-A512-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1bf1d931-279f-4cc9-8176-71033d1b1dbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A512-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37335e53-32a2-44b8-8614-2c5154097642

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 2: 24,090; copy number 3: 34; copy number 4: 29,569; copy number 5: 148; copy number 6: 5,060; copy number 7: 47; copy number 8: 850.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A512-01A-11D-A26L-01): tumor purity 0.77, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:17,134,982–17,797,124, 4 genes (within-gene range 0–4): CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
